Somatic mutation profile of tumor specimen TARGET-10-PAPGKP-09A (aliquot TARGET-10-PAPGKP-09A-01D) from TARGET case TARGET-10-PAPGKP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,285 days).
Specimen TARGET-10-PAPGKP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8348e67e-9cae-49e0-a6a2-a5d6584204b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGKP-10A (Blood Derived Normal), aliquot TARGET-10-PAPGKP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58c3792a-cbf4-418b-a688-b9eadaafe26b

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH7 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs565395707, COSV100414163; called by muse, mutect2
- KMT2D | c.14251+1G>C p.X4751_splice | Splice Site (SNP) | VAF 18/38 reads (47%) | catalogued as CS114928, COSV56442019; called by muse, mutect2, varscan2
- NLRP9 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs748100092; called by muse, mutect2, varscan2
- SLC44A5 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as COSV63766420; called by muse, mutect2, varscan2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- N4BP3 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
